Gene-level copy-number profile of tumor specimen TCGA-KC-A7FA-01A from TCGA case TCGA-KC-A7FA, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.5 years (23,208 days).
Specimen TCGA-KC-A7FA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.9c292588-adaa-46a6-8d53-755a910b8005.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KC-A7FA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/62841630-38b1-465c-814c-3e142f23b9d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 5,968; copy number 2: 52,102; copy number 3: 1,701.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KC-A7FA-01A-21D-A33S-01): tumor purity 0.74, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 48 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:49,847,018–51,151,367, 47 genes: AC027348.1, AC007603.2, AC007603.1, RPL34P29, AC007603.3, CNEP1R1, AC007610.1, AC007610.3, Metazoa_SRP, ACTG1P16, HEATR3, AC007610.4, RNY4P3, AC007610.2, AC007610.5, RPL10P14, SNORA70, TENT4B, ADCY7, MIR6771, BRD7, AC007493.2, LINC02178, AC007493.1, NKD1, AC007608.2, AC007608.4, AC007608.1, AC007608.3, SNX20, NOD2, AC007728.3, AC007728.2, CYLD, MIR3181, AC007728.1, LINC02168, LINC02128, AC025810.1, RNA5SP426, LINC02127, AC027688.1, AC027688.2, AC009166.3, SOD1P2, SALL1, AC009166.1.
- chr16:51,176,066–51,178,898, 1 gene: AC009166.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,582. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
